Somatic mutation profile of tumor specimen TCGA-IA-A40U-01A (aliquot TCGA-IA-A40U-01A-11D-A25F-10) from TCGA case TCGA-IA-A40U, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 56.0 years (20,463 days).
Specimen TCGA-IA-A40U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e5bec80-3268-432f-9286-e6edc1c37875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A40U-10A (Blood Derived Normal), aliquot TCGA-IA-A40U-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb9ed56b-b890-4bf7-b99c-88fcf4b34bf6

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 6, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, Splice Site 2, Nonstop Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.2028A>C p.E676D | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV57076955; called by muse, mutect2, varscan2
- C16orf46 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 79/294 reads (27%) | catalogued as COSV55152330; called by muse, mutect2, varscan2
- CCDC3 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV66560935; called by muse, mutect2, varscan2
- CCDC66 | c.978A>C p.Q326H (on ENST00000394672 / NM_001353147.1; = p.Q292H on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.025); catalogued as COSV58307242; called by muse, mutect2, varscan2
- CDKL2 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56734682; called by muse, varscan2
- CLMN | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV54186100; called by muse, mutect2, varscan2
- CNKSR3 | c.1237A>G p.N413D | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.131); catalogued as COSV70481411; called by muse, mutect2, varscan2
- COL12A1 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.045); catalogued as COSV59403091; called by mutect2, varscan2
- COPG2 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58406336; called by muse, mutect2, varscan2
- CSPG4 | c.6651C>G p.F2217L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57899348; called by muse, mutect2, varscan2
- ERBB4 | c.3818G>A p.R1273Q | Missense Mutation (SNP) | VAF 105/187 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.273); catalogued as rs1256468343, COSV61509539; called by muse, mutect2, varscan2
- FAT4 | c.3433G>A p.D1145N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV67895083; called by muse, mutect2, varscan2
- GEMIN5 | c.3232G>A p.V1078I | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs144363013; called by muse, mutect2, varscan2
- GLG1 | c.2135T>G p.I712R | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.937); catalogued as COSV52671824; called by muse, mutect2, varscan2
- HOXC10 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV57726826; called by muse, mutect2, varscan2
- INPPL1 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748148293, COSV53357900; called by muse, mutect2, varscan2
- KCNJ12 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782136725, COSV59163298, COSV59169171; called by muse, mutect2
- LRIG3 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs373824765; called by muse, mutect2, varscan2
- MET | c.1915A>C p.I639L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59265930; called by muse, mutect2, varscan2
- MFHAS1 | c.3155A>G p.Q1052R | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52285646; called by muse, mutect2
- MMP27 | c.1277A>C p.D426A | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52782003; called by muse, mutect2
- MZF1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1283661187, COSV53042660; called by muse, mutect2, varscan2
- NCKAP1L | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 88/516 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as rs767798885, COSV53210316; called by muse, mutect2
- NCOR1 | c.4798C>A p.Q1600K | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.366); catalogued as COSV51987660; called by muse, mutect2, varscan2
- NUP155 | c.2893T>C p.F965L (on ENST00000231498 / NM_153485.3; = p.F906L on NM_004298.4) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as rs780165777, COSV51532949; called by muse, mutect2, varscan2
- OR2T3 | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV62083099; called by muse, mutect2, varscan2
- PAFAH1B2 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs569223304, COSV59167323; called by muse, mutect2, varscan2
- PMF1 | c.618A>C p.*206Cext*70 | Nonstop Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as COSV99430719; called by muse, mutect2, varscan2
- PSD | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50052609; called by muse, mutect2, varscan2
- PSMA1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 37/105 reads (35%) | catalogued as COSV67166119; called by muse, mutect2, varscan2
- RBM19 | c.37A>G p.M13V | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.493); catalogued as rs747154028, COSV55696221; called by muse, varscan2
- RBM19 | c.37-1G>A p.X13_splice | Splice Site (SNP) | VAF 76/112 reads (68%) | catalogued as COSV55689185; called by muse, varscan2
- RECQL | c.1933A>C p.K645Q | Missense Mutation (SNP) | VAF 228/364 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53711059; called by muse, mutect2, varscan2
- RHCG | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 146/330 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs753849676, COSV51517471; called by muse, mutect2, varscan2
- RNF14 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100641309, COSV61662676; called by muse, mutect2, varscan2
- STUB1 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 146/256 reads (57%) | catalogued as COSV50198309; called by muse, mutect2, varscan2
- TRPV1 | c.1718T>C p.I573T | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV51522166; called by muse, mutect2
- TULP1 | c.1132C>G p.R378G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57693435; called by muse, mutect2, varscan2
- WDR54 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV51965264; called by muse, mutect2, varscan2
- LRRC37A | c.4806dup p.V1603Cfs*13 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, varscan2
- MAP4K1 | c.746_752del p.N249Tfs*5 | Frame Shift Del (DEL) | VAF 46/146 reads (32%) | called by mutect2, pindel, varscan2
- PRKCI | c.1431del p.K477Nfs*11 | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | called by mutect2, pindel, varscan2
- ARMH3 | c.312G>A p.L104= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60751390; called by muse, mutect2, varscan2
- DNAH17 | c.10419C>A p.V3473= | Silent (SNP) | VAF 113/226 reads (50%) | catalogued as COSV67758979; called by muse, mutect2, varscan2
- INO80D | c.255C>T p.I85= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as rs770921823, COSV68959661; called by muse, mutect2, varscan2
- TAB1 | c.609G>A p.L203= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as rs1185265362, COSV53372529; called by muse, mutect2, varscan2
- TRIM42 | c.792G>A p.K264= | Silent (SNP) | VAF 95/232 reads (41%) | catalogued as COSV53885114, COSV53885345; called by muse, mutect2, varscan2
- UBC | c.663G>T p.L221= | Silent (SNP) | VAF 208/833 reads (25%) | catalogued as COSV100298777; called by muse, mutect2, varscan2
- CARD19 | c.*1168T>G | 3'UTR (SNP) | VAF 22/53 reads (42%) | catalogued as COSV64936098; called by muse, mutect2, varscan2
- CARD19 | c.*1169G>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | catalogued as COSV64936100; called by muse, mutect2, varscan2
- VSTM4 | c.457+3804_457+3807del | Intron (DEL) | VAF 30/118 reads (25%) | called by mutect2, pindel, varscan2
